Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8604, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8604-01A (Primary Tumor).

Stomach, subtotal gastrectomy:

Advanced gastric carcinoma

(Muc2(-)/Muc5AC(-)/Muc6(-)/CD10(+ +)/cERB2(-),I type)

1. Location : lower third, Center at antrum, lesser curvature
2. Gross type : Borrmann type 2 (ulcerofungating)
3. Histologic type : Adenocarcinoma, tubular moderately differentiated (tub2)
4. Histologic type by Lauren : intestinal
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 8.7x8.0cm
7. Depth of invasion : invades subserosa (pT3),
8. Resection margin : free from carcinoma
safety margins: distal 3.0cm, proximal 1.5cm
9. Lymph node metastasis : no metastasis in 27 regional lymph nodes (pN0)
(lesser curvature 0/18, greater curvature 0/8, LN 0/1)
10. Lymphatic invasion : not identified
11. Venous invasion : present, mild
12. Perineural invasion : not identified

Specimen labeled as "anvil ring", biopsy:

No tumor.

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file ac3e6cf5-0ec7-4011-877c-62afb9f88a76 (TCGA-HU-8604.7E645DFA-F080-419E-B7A7-12A46AF41D3A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).